Somatic mutation profile of tumor specimen TCGA-12-0820-01A (aliquot TCGA-12-0820-01A-01W-0424-08) from TCGA case TCGA-12-0820, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.7 years (14,878 days).
Specimen TCGA-12-0820-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6333c93b-5919-490e-ba88-05392036c506.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0820-10A (Blood Derived Normal), aliquot TCGA-12-0820-10A-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60ba3a2b-e2b1-4fd2-9511-fba63245639f

The open-access MAF lists 60 somatic variants for this specimen: 54 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 45, Silent 6, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIM2 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 23/600 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as COSV100931048; called by muse, mutect2
- AIM2 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 24/595 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs1294740350, COSV100931049; called by muse, mutect2
- ANP32D | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs753906042, COSV99874255; called by muse, mutect2, varscan2
- CDK11A | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100651720; called by muse, mutect2
- CLEC4F | c.1260G>T p.E420D | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55479429, COSV99713668; called by muse, mutect2, varscan2
- CNTNAP2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 221/868 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.845); catalogued as rs956320440, COSV100674155, COSV62150880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCC | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 240/593 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.127); catalogued as rs979054696, COSV100499139; called by muse, mutect2, varscan2
- DNAI3 | c.1600dup p.Q534Pfs*12 | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | catalogued as rs781774059; called by pindel, varscan2
- EIF5B | c.3614G>A p.S1205N | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99177081; called by muse, mutect2, varscan2
- FASTKD1 | c.2515A>G p.I839V | Missense Mutation (SNP) | VAF 183/501 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs751830294, COSV99500315; called by muse, mutect2, varscan2
- FBH1 | c.2225G>A p.G742E (on ENST00000362091 / NM_178150.3; = p.G793E on NM_032807.4) | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV100758682; called by muse, mutect2, varscan2
- FCSK | c.83-1G>T p.X28_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99850710; called by muse, mutect2
- FLG | c.6388G>A p.A2130T | Missense Mutation (SNP) | VAF 22/540 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs1273730573, COSV100911392; called by muse, mutect2
- GDF3 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 376/850 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as COSV100325210; called by muse, mutect2
- GLI2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100082846; called by muse, mutect2, varscan2
- GRM3 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1235603640, COSV64475802; called by muse, mutect2, varscan2
- IFI16 | c.2225C>T p.P742L (on ENST00000295809 / NM_001364867.2; = p.P686L on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); catalogued as rs772714012, COSV99857345; called by muse, mutect2, varscan2
- IKZF3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 72/746 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs139539885, COSV99499477; called by muse, mutect2
- INPP5D | c.530C>T p.P177L (on ENST00000445964 / NM_001017915.3; = p.P176L on NM_005541.5) | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs778985157, COSV64041828; called by muse, mutect2, varscan2
- KIT | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 156/400 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV99853812; called by muse, mutect2, varscan2
- KPRP | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 132/390 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs1445616839, COSV64221535; called by muse, mutect2, varscan2
- KRBOX4 | c.172T>C p.F58L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99994229; called by muse, mutect2
- LHFPL1 | c.594A>G p.I198M | Missense Mutation (SNP) | VAF 114/136 reads (84%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100914442; called by muse, mutect2, varscan2
- MYH4 | c.1183T>C p.S395P | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV99700918; called by muse, mutect2, varscan2
- NEURL4 | c.4222G>C p.E1408Q | Missense Mutation (SNP) | VAF 29/373 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.289); catalogued as COSV100222855; called by muse, mutect2
- NOTCH3 | c.6140G>A p.G2047E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.573); catalogued as COSV99656709; called by mutect2, varscan2
- NOX3 | c.1201G>T p.V401L | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99342961; called by muse, mutect2, varscan2
- NSMAF | c.1502A>T p.Y501F | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs538089506, COSV99232697; called by muse, mutect2, varscan2
- OR10G8 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs187776113; called by muse, mutect2, varscan2
- OR10J3 | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 39/92 reads (42%) | catalogued as COSV100171682; called by muse, mutect2, varscan2
- OR2A14 | c.889A>C p.K297Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV101376447; called by muse, mutect2, varscan2
- PDX1 | c.363G>A p.W121* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV101124086; called by muse, mutect2
- PIGV | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 33/720 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV99314865; called by muse, mutect2
- PIGV | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 58/1634 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV50291142, COSV99314868; called by muse, mutect2
- PNPLA2 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100352024; called by muse, varscan2
- POP7 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 34/465 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100292166; called by muse, mutect2
- PRSS35 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1460269196, COSV63800358, COSV63801021; called by muse, mutect2, varscan2
- PTPRH | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771367694, COSV99670905; called by muse, mutect2, varscan2
- ROCK2 | c.1730C>G p.T577S | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV99837228; called by muse, mutect2, varscan2
- SNW1 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 89/311 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99473142; called by muse, mutect2, varscan2
- SRC | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 259/1125 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as rs751005087, COSV100658022; called by muse, mutect2, varscan2
- STK39 | c.1429G>C p.D477H | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100596458; called by muse, mutect2, varscan2
- SYNE1 | c.21737A>G p.D7246G (on ENST00000367255 / NM_182961.4; = p.D7175G on NM_033071.3) | Missense Mutation (SNP) | VAF 311/1494 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1408301596, COSV99559300; called by muse, varscan2
- TNKS | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs373493403; called by muse, mutect2, varscan2
- VAV1 | c.2417G>C p.G806A | Missense Mutation (SNP) | VAF 190/630 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100408874; called by muse, mutect2, varscan2
- XRN1 | c.4220-1G>A p.X1407_splice | Splice Site (SNP) | VAF 20/68 reads (29%) | catalogued as rs868028980, COSV99064136, COSV99377689; called by muse, mutect2, varscan2
- ZNF664 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100544424, COSV100544487; called by muse, mutect2, varscan2
- ZNF676 | c.1130del p.A377Vfs*153 (on ENST00000650058; = p.A345Vfs*153 on NM_001001411.3) | Frame Shift Del (DEL) | VAF 24/148 reads (16%) | catalogued as COSV101236124; called by mutect2, pindel, varscan2
- CITED2 | c.432C>G p.H144Q | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2
- PSMA7 | c.643del p.Q215Nfs*6 | Frame Shift Del (DEL) | VAF 85/509 reads (17%) | called by mutect2, pindel, varscan2
- RTL6 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TEKT3 | c.694_697del p.R232* | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | called by pindel, varscan2
- TIPARP | c.1583G>C p.R528T | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- TRAPPC4 | c.549_551del p.K183del | In Frame Del (DEL) | VAF 20/180 reads (11%) | called by mutect2, varscan2
- CDK11A | c.93G>A p.E31= | Silent (SNP) | VAF 48/234 reads (21%) | catalogued as rs1227718524, COSV100651719; called by muse, mutect2
- FOXRED1 | c.426G>A p.L142= | Silent (SNP) | VAF 190/346 reads (55%) | catalogued as COSV99702711; called by mutect2, varscan2
- GLP1R | c.396G>A p.G132= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs866631422, COSV100952539; called by muse, mutect2, varscan2
- HERC2 | c.11154C>T p.L3718= | Silent (SNP) | VAF 67/147 reads (46%) | catalogued as rs1200249761, COSV99872477; called by muse, mutect2, varscan2
- TUBGCP6 | c.84G>A p.V28= | Silent (SNP) | VAF 135/193 reads (70%) | catalogued as COSV99352253; called by muse, mutect2, varscan2
- ZNF676 | c.1311C>G p.S437= (on ENST00000650058; = p.S405= on NM_001001411.3) | Silent (SNP) | VAF 40/176 reads (23%) | catalogued as COSV101236153; called by muse, mutect2, varscan2
